Somatic mutation profile of tumor specimen bc9fe67f-c4a2-43ba-87bd-438bda (aliquot bc9fe67f-c4a2-43ba-87bd-438bda_D6_1) from CPTAC case 11BR011, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.4 years (26,097 days).
Specimen bc9fe67f-c4a2-43ba-87bd-438bda: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3153f74a-1bff-4127-8006-f0e8fc430820.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 85252bdd-206b-486f-b12a-705fcb (Blood Derived Normal), aliquot 85252bdd-206b-486f-b12a-705fcb_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e74b835-5272-42ee-9b2e-c7f0dc13216c

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Frame Shift Del 2, Intron 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 62/281 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ANKLE1 | c.738C>A p.S246R (on ENST00000394458; = p.S192R on NM_152363.6) | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV63921183; called by muse, mutect2, varscan2
- CADPS | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1015833872; called by muse, mutect2, varscan2
- CEP295 | c.5411A>G p.D1804G | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs1182074669; called by muse, mutect2, varscan2
- DPP6 | c.2036G>A p.R679Q (on ENST00000377770 / NM_001364500.2; = p.R617Q on NM_001936.5) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as rs765183208, COSV100126407; called by muse, mutect2, varscan2
- FBXL15 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | catalogued as rs933256052; called by muse, mutect2, varscan2
- PHYHIP | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.172); catalogued as rs748331111; called by muse, mutect2, varscan2
- SCEL | c.1333C>T p.Q445* (on ENST00000349847 / NM_144777.3; = p.Q425* on NM_003843.4) | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as rs1344768968; called by muse, mutect2, varscan2
- SYBU | c.939G>T p.W313C (on ENST00000276646 / NM_001099754.2; = p.W312C on NM_017786.6) | Missense Mutation (SNP) | VAF 103/253 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52620555, COSV52624096; called by muse, mutect2, varscan2
- UTRN | c.6835C>T p.R2279C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs114254210, COSV62340532; called by muse, mutect2, varscan2
- BRAP | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- C1orf43 | c.324T>A p.D108E (on ENST00000368521 / NM_001297718.2; = p.D74E on NM_015449.4) | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CEMIP2 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CENPF | c.6716T>G p.L2239R | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- FAM102A | c.60_64del p.E20Dfs*47 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- MMP3 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2
- NKTR | c.1210C>G p.Q404E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ORMDL1 | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PCDHB2 | c.2044C>A p.Q682K | Missense Mutation (SNP) | VAF 82/655 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAF6 | c.824del p.N275Tfs*8 | Frame Shift Del (DEL) | VAF 26/289 reads (9%) | called by mutect2, pindel
- TUFT1 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- ZIC1 | c.1073G>C p.S358T | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CLSTN2 | c.126A>T p.P42= | Silent (SNP) | VAF 27/175 reads (15%) | called by muse, mutect2, varscan2
- NCOA3 | c.3918G>C p.P1306= (on ENST00000371998 / NM_181659.3; = p.P1302= on NM_006534.4) | Silent (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- PLBD1 | c.870T>C p.F290= | Silent (SNP) | VAF 69/394 reads (18%) | called by muse, mutect2, varscan2
- RNF139 | c.879C>T p.G293= | Silent (SNP) | VAF 51/559 reads (9%) | catalogued as COSV52678973; called by muse, mutect2
- MMP17 | c.968+28C>T | Intron (SNP) | VAF 14/148 reads (9%) | catalogued as rs979007463, COSV62180959; called by muse, mutect2
- RUNX1T1 | c.741-2718C>T | Intron (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
